HCMI case HCM-EXPT-1255-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/b2bcc99e-10ea-42e7-a1d9-181f0732d25e

Demographics
Sex at birth: female; Days to birth: -28,306 days (77.5 years before the index date).

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C25.3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreatic duct; Classification of tumor: primary; Prior treatment: No; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIB; Uicc pathologic t: T2; Uicc staging system edition: 7th.
   Recorded as not given: neoadjuvant treatment (type not reported).

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Biospecimens (1 sample)
- Sample HCM-EXPT-1255-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
